Somatic mutation profile of tumor specimen TCGA-CD-5813-01A (aliquot TCGA-CD-5813-01A-11D-1600-08) from TCGA case TCGA-CD-5813, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.2 years (21,995 days).
Specimen TCGA-CD-5813-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 711fe41d-1c21-4405-b531-c4c1ed8edc5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5813-10A (Blood Derived Normal), aliquot TCGA-CD-5813-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89c995ea-909e-4b72-8e1d-a31e1dc53324

The open-access MAF lists 177 somatic variants for this specimen: 136 protein-altering or splice-affecting, 37 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 37, Splice Site 8, Nonsense Mutation 5, Frame Shift Ins 4, In Frame Del 2, 5'UTR 2, Intron 1, Splice Region 1, RNA 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH15 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs137853001, CM012633, COSV57282024; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 29/62 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.2883+1G>A p.X961_splice | Splice Site (SNP) | VAF 15/110 reads (14%) | catalogued as COSV64986897; called by muse, mutect2, varscan2
- ACKR2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56176699; called by muse, mutect2, varscan2
- ADGRB3 | c.3370C>T p.R1124C | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896719594, COSV53238070, COSV99487208; called by muse, mutect2, varscan2
- AGBL5 | c.1042T>C p.S348P | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1362720662, COSV59936962; called by muse, mutect2, varscan2
- AHNAK | c.10030G>A p.E3344K | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs769435744, COSV57217931; called by muse, mutect2, varscan2
- ALK | c.4411G>A p.V1471M | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs201759867, COSV66574160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD50 | c.3953C>T p.P1318L | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs748326840, COSV72385811; called by muse, mutect2, varscan2
- ANXA9 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV64485080; called by muse, mutect2
- APBA2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs1416887852, COSV68792476; called by muse, mutect2, varscan2
- ARID4A | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794492, COSV62164720; called by muse, mutect2, varscan2
- ASB11 | c.309C>A p.H103Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60355637; called by muse, mutect2, varscan2
- ATP5F1B | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV56261373; called by muse, mutect2, varscan2
- ATXN2L | c.1999A>T p.N667Y | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57373111; called by muse, mutect2, varscan2
- BRSK1 | c.1889C>G p.S630W | Missense Mutation (SNP) | VAF 94/533 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58664618, COSV58667729; called by muse, mutect2, varscan2
- CALM2 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV55399076, COSV55400291; called by muse, mutect2, varscan2
- CAMTA1 | c.4324A>T p.S1442C | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57897973, COSV57908538; called by muse, mutect2
- CCDC88B | c.146T>C p.L49S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV57266799; called by muse, mutect2, varscan2
- CD2 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65643364; called by muse, mutect2
- CDH1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55735012; called by muse, mutect2, varscan2
- CDH17 | c.553A>T p.K185* | Nonsense Mutation (SNP) | VAF 46/691 reads (7%) | catalogued as COSV50331394; called by muse, mutect2
- CDH9 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50284820, COSV50313302; called by muse, mutect2, varscan2
- CFAP61 | c.727A>C p.S243R | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV55634734; called by muse, mutect2
- CNNM1 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV63202261; called by muse, mutect2, varscan2
- CNTN4 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs987280347, COSV68578447; called by muse, varscan2
- COL18A1 | c.2672T>C p.F891S (on ENST00000359759 / NM_130444.3; = p.F656S on NM_030582.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV62703287; called by muse, mutect2, varscan2
- CORO2B | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV55954310; called by muse, mutect2, varscan2
- CPB2 | c.797-1G>A p.X266_splice | Splice Site (SNP) | VAF 26/152 reads (17%) | catalogued as COSV51675384; called by muse, mutect2, varscan2
- CRYBG3 | c.6056G>C p.R2019T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs766007362, COSV51713239; called by muse, mutect2, varscan2
- CSPG4 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs140979403; called by muse, mutect2, varscan2
- CYLC2 | c.469G>C p.A157P | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV66338122; called by muse, mutect2, varscan2
- DNM1 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.713); catalogued as COSV100360284; called by muse, varscan2
- DOP1A | c.3946G>C p.E1316Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV52712468; called by muse, mutect2, varscan2
- DOP1B | c.2060T>A p.I687N | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.386); catalogued as rs926225796, COSV67693420, COSV67693904; called by muse, mutect2
- DPYS | c.855G>T p.W285C | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV60910154; called by muse, mutect2, varscan2
- DYNC1H1 | c.11942-2A>G p.X3981_splice | Splice Site (SNP) | VAF 89/352 reads (25%) | catalogued as COSV64138479; called by muse, mutect2, varscan2
- EPHB1 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); catalogued as COSV101213228, COSV67664069; called by muse, mutect2, varscan2
- EPHB1 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs373797543, COSV67655662, COSV67667897; called by muse, mutect2, varscan2
- ERBB4 | c.2518G>A p.V840I | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs369248674, COSV61493011; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERF | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1233632467, COSV55896484; called by muse, mutect2, varscan2
- FAT3 | c.3736G>T p.D1246Y | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53130925; called by muse, mutect2, varscan2
- FAXC | c.147T>G p.D49E | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.021); catalogued as COSV67602611; called by muse, mutect2
- FLG | c.5756G>T p.S1919I | Missense Mutation (SNP) | VAF 142/826 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777529436, COSV64243507; called by muse, mutect2, varscan2
- GRM2 | c.2107C>G p.P703A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99623111; called by muse, mutect2, varscan2
- GTDC1 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs369784077; called by muse, mutect2, varscan2
- GTF2I | c.1948A>T p.I650F (on ENST00000573035 / NM_032999.4; = p.I609F on NM_001518.5) | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV100259874; called by muse, mutect2, varscan2
- HAUS3 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV99704377; called by muse, mutect2, varscan2
- HECW1 | c.3814C>T p.R1272W | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760419912, COSV67832800; called by muse, mutect2, varscan2
- HMCN1 | c.12377G>A p.R4126H | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs141573564; called by muse, mutect2, varscan2
- HP1BP3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV56563255; called by muse, mutect2, varscan2
- HSPA8 | c.106C>G p.R36G | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.983); catalogued as COSV57084460; called by muse, mutect2, varscan2
- KAT2B | c.2351C>G p.S784C | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV55431029; called by muse, mutect2, varscan2
- KCNN2 | c.1326G>C p.K442N (on ENST00000264773; = p.K654N on NM_021614.4) | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53291941; called by muse, mutect2, varscan2
- KCNV1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52084789; called by muse, mutect2, varscan2
- KCTD19 | c.2527A>G p.I843V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58573460; called by muse, mutect2, varscan2
- KIAA1210 | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs745577960, COSV101274165, COSV101274303, COSV68176979; called by muse, mutect2, varscan2
- KIR3DL2 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 159/1285 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99552307; called by muse, mutect2, varscan2
- LCMT2 | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59790842; called by muse, mutect2, varscan2
- LRRC7 | c.3485A>T p.E1162V (on ENST00000651989 / NM_001370785.2; = p.E1129V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV50491327; called by muse, mutect2, varscan2
- LRRIQ1 | c.3350A>C p.N1117T | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67832974; called by muse, mutect2, varscan2
- LUZP1 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV56502601; called by muse, mutect2, varscan2
- MAGI1 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1451180881, COSV58332670; called by muse, mutect2, varscan2
- MAP3K21 | c.1767dup p.G590Rfs*14 | Frame Shift Ins (INS) | VAF 36/128 reads (28%) | catalogued as rs1412993608; called by mutect2, pindel, varscan2
- MEF2D | c.101A>C p.E34A | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61729257; called by muse, mutect2
- MXRA5 | c.5279G>T p.R1760I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV54239778; called by muse, mutect2, varscan2
- MYCL | c.340G>T p.A114S (on ENST00000372816 / NM_001033081.3; = p.A144S on NM_005376.5) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV100862381, COSV65693257; called by muse, varscan2
- MYO1E | c.1218T>G p.N406K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55689781; called by muse, mutect2, varscan2
- MYO9A | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1297349712, COSV61853222; called by muse, mutect2, varscan2
- NACA | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV63270751; called by muse, mutect2, varscan2
- NIPSNAP2 | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59051621; called by muse, mutect2, varscan2
- NLRP2 | c.688T>G p.W230G | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775731182, COSV54756658; called by muse, mutect2
- OTOP1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs200612216; called by muse, mutect2, varscan2
- PBRM1 | c.3388-2A>C p.X1130_splice (on ENST00000296302 / NM_001366071.2; = p.X1105_splice on NM_018313.5) | Splice Site (SNP) | VAF 30/196 reads (15%) | catalogued as COSV56284329; called by muse, mutect2, varscan2
- PBX1 | c.1204A>G p.N402D | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV63345303; called by muse, mutect2, varscan2
- PCDH12 | c.2474C>T p.T825M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as COSV51520125; called by muse, mutect2
- PDE1C | c.1936T>A p.S646T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV58517931; called by muse, mutect2, varscan2
- PDPR | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs567832669, COSV99848801; called by muse, mutect2, varscan2
- PHOSPHO2 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV55868081; called by muse, mutect2, varscan2
- PPP2R3A | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53866289; called by muse, mutect2, varscan2
- PREX2 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 43/679 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV55779602; called by muse, mutect2
- PRICKLE2 | c.1156A>G p.R386G (on ENST00000295902; = p.R330G on NM_198859.4) | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778386656, COSV55767853; called by muse, mutect2, varscan2
- PRKCE | c.1943A>C p.K648T | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV60322198; called by muse, mutect2, varscan2
- PSD4 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99831422; called by muse, mutect2, varscan2
- PTDSS1 | c.1005G>A p.V335= | Splice Region (SNP) | VAF 72/474 reads (15%) | catalogued as COSV61265214; called by muse, mutect2, varscan2
- QPCT | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV58120212; called by muse, mutect2, varscan2
- REN | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65817474; called by muse, mutect2
- REST | c.2515G>T p.E839* | Nonsense Mutation (SNP) | VAF 40/311 reads (13%) | catalogued as rs1553904378, COSV58361386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIC1 | c.2228G>C p.G743A | Missense Mutation (SNP) | VAF 11/285 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV52611277; called by muse, mutect2
- RIPOR1 | c.401G>A p.R134Q (on ENST00000379312 / NM_001193522.2; = p.R130Q on NM_024519.4) | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV50231463; called by muse, mutect2, varscan2
- ROCK2 | c.3979C>G p.L1327V | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV59959732; called by muse, mutect2, varscan2
- RYR3 | c.10444C>T p.R3482W (on ENST00000389232; = p.R3483W on NM_001036.6) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66796424; called by muse, mutect2
- SCAI | c.1657A>C p.M553L (on ENST00000336505 / NM_001144877.3; = p.M576L on NM_173690.5) | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57176133; called by muse, mutect2, varscan2
- SEMA4A | c.464A>T p.E155V | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV61773134; called by muse, mutect2, varscan2
- SEMG1 | c.948C>G p.S316R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54873421; called by muse, mutect2
- SLC12A6 | c.1338T>A p.N446K (on ENST00000354181 / NM_001365088.1; = p.N395K on NM_005135.2) | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV51627467; called by muse, mutect2
- SLC25A39 | c.854T>C p.V285A (on ENST00000377095 / NM_001143780.3; = p.V277A on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV56587961; called by muse, mutect2, varscan2
- SLC25A46 | c.620+1G>A p.X207_splice | Splice Site (SNP) | VAF 18/79 reads (23%) | catalogued as rs1171977270, COSV63506828; called by muse, mutect2, varscan2
- SLC26A3 | c.2205+1G>A p.X735_splice | Splice Site (SNP) | VAF 32/224 reads (14%) | catalogued as COSV60640980; called by muse, mutect2, varscan2
- SNX15 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as COSV57247427; called by muse, mutect2, varscan2
- SP100 | c.1972A>C p.S658R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV50976307; called by muse, mutect2, varscan2
- SPX | c.305dup p.N102Kfs*3 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | catalogued as rs750111618; called by mutect2, varscan2
- STAG1 | c.3383C>A p.P1128H | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.227); catalogued as COSV52614079, COSV99364143; called by muse, mutect2, varscan2
- TBCEL | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs778000015, COSV52460614; called by muse, mutect2, varscan2
- TCF20 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV59493230; called by muse, mutect2, varscan2
- TENM2 | c.4085C>T p.A1362V (on ENST00000518659 / NM_001122679.2; = p.A1123V on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV69133848; called by muse, mutect2, varscan2
- TET2 | c.3409+2T>C p.X1137_splice (on ENST00000380013 / NM_001127208.3; = p.G1137= on NM_017628.4) | Splice Site (SNP) | VAF 26/165 reads (16%) | catalogued as COSV54405796, COSV54417773; called by muse, mutect2, varscan2
- TMCC2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.98); catalogued as rs777290569, COSV58004463; called by muse, mutect2, varscan2
- TNC | c.6364T>A p.F2122I | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60784508; called by muse, mutect2, varscan2
- TRIB3 | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV99423984; called by muse, mutect2
- TRIM24 | c.2995G>A p.E999K (on ENST00000343526 / NM_015905.3; = p.E965K on NM_003852.4) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs554322561, COSV58973884; called by muse, mutect2
- TRPM1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs368722464; called by muse, mutect2, varscan2
- TRPM6 | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62514586; called by muse, mutect2, varscan2
- TSR3 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV50104309, COSV50105095; called by muse, mutect2, varscan2
- TTC37 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62455384; called by muse, mutect2, varscan2
- TTN | c.101317G>C p.E33773Q (on ENST00000591111; = p.E26349Q on NM_003319.4) | Missense Mutation (SNP) | VAF 30/276 reads (11%) | PolyPhen benign (0.062); catalogued as rs1558984927, COSV60150968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.89857A>C p.S29953R (on ENST00000591111; = p.S22529R on NM_003319.4) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | PolyPhen probably damaging (0.997); catalogued as COSV60150996; called by muse, mutect2, varscan2
- TYW1 | c.345A>T p.E115D | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62753375; called by muse, mutect2, varscan2
- UNC5B | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770198176, COSV58978137, COSV58979218; called by muse, mutect2, varscan2
- VPS13D | c.3045T>A p.D1015E | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50649195; called by muse, mutect2, varscan2
- VRTN | c.1503G>T p.R501S | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56440081, COSV56441901; called by muse, mutect2, varscan2
- VWC2 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1428418971, COSV61482544; called by muse, mutect2, varscan2
- XIAP | c.192T>G p.F64L | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63022702; called by muse, mutect2
- YDJC | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.248); catalogued as COSV53038094; called by muse, mutect2, varscan2
- ZNF154 | c.457A>T p.R153* | Nonsense Mutation (SNP) | VAF 155/1280 reads (12%) | catalogued as COSV70745193; called by muse, mutect2, varscan2
- ZNF594 | c.725A>G p.N242S | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV68385666; called by muse, mutect2, varscan2
- ZNF615 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 158/683 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs749865669, COSV65033975; called by muse, mutect2, varscan2
- ZNF708 | c.1451G>C p.S484T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs773306265, COSV63607763; called by muse, mutect2, varscan2
- ABCA8 | c.3162dup p.D1055Rfs*40 | Frame Shift Ins (INS) | VAF 39/170 reads (23%) | called by mutect2, pindel, varscan2
- CITED2 | c.133dup p.Q45Pfs*50 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- DDX23 | c.106_136del p.R36Gfs*129 | Frame Shift Del (DEL) | VAF 25/194 reads (13%) | called by mutect2, pindel
- ELF3 | c.410_418del p.S137_I139del | In Frame Del (DEL) | VAF 29/125 reads (23%) | called by pindel, varscan2
- KIR3DL3 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 152/606 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP28 | c.508_516del p.F170_E172del | In Frame Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- R3HDM2 | c.1238_1240dup p.Q413dup | In Frame Ins (INS) | VAF 30/134 reads (22%) | called by mutect2, pindel, varscan2
- UBR2 | c.511_531+19del p.X171_splice | Splice Site (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel
- ABCA12 | c.1443C>T p.T481= (on ENST00000272895 / NM_173076.3; = p.T163= on NM_015657.3) | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs143605938, COSV55964344; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3615C>T p.I1205= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs530684002, COSV65893672; called by muse, mutect2, varscan2
- ARFGEF1 | c.4716T>A p.I1572= | Silent (SNP) | VAF 21/153 reads (14%) | catalogued as COSV51611212, COSV99141071; called by muse, mutect2, varscan2
- CADPS | c.813G>A p.E271= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as rs1175938123, COSV51887198; called by muse, mutect2, varscan2
- CAND1 | c.132T>C p.D44= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as rs1444103128, COSV73338905; called by muse, mutect2
- CASP2 | c.1029C>T p.C343= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs746887367, COSV60082618; called by muse, mutect2, varscan2
- CDH18 | c.840A>G p.S280= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as COSV56933486; called by muse, mutect2, varscan2
- COL1A1 | c.3345C>A p.G1115= | Silent (SNP) | VAF 14/183 reads (8%) | catalogued as COSV56806602; called by muse, mutect2
- CSMD3 | c.216T>C p.L72= | Silent (SNP) | VAF 53/669 reads (8%) | catalogued as COSV52208595; called by muse, mutect2
- CYB5B | c.18G>T p.A6= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV57174832; called by muse, mutect2, varscan2
- DDX41 | c.906C>T p.S302= | Silent (SNP) | VAF 51/317 reads (16%) | catalogued as rs1465152201, COSV57252986; called by muse, mutect2, varscan2
- DGKB | c.309T>A p.A103= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV51794368; called by muse, mutect2, varscan2
- DHX38 | c.2514T>C p.D838= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV51698860; called by muse, mutect2, varscan2
- ELP2 | c.900C>T p.V300= | Silent (SNP) | VAF 26/322 reads (8%) | catalogued as rs1191043670, COSV60852026; called by muse, mutect2
- FBXO7 | c.1413G>A p.T471= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs375919269; called by muse, mutect2, varscan2
- FLNA | c.999C>T p.T333= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1167180795, COSV61036581; ClinVar: likely benign; called by muse, mutect2, varscan2
- GGT1 | c.816G>A p.V272= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1466513159, COSV99959283; called by muse, varscan2
- HECW2 | c.2475C>T p.Y825= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs141027520; called by muse, mutect2, varscan2
- HSPA14 | c.75G>A p.V25= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as rs368167301, COSV65684581; called by muse, mutect2, varscan2
- HSPG2 | c.2700G>T p.G900= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV65973277; called by muse, mutect2, varscan2
- IFT81 | c.1105T>C p.L369= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as rs796639459, COSV54363853; called by muse, mutect2, varscan2
- IRF8 | c.591G>A p.A197= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1469176664, COSV51896798, COSV51896937; called by muse, mutect2, varscan2
- KCNK1 | c.402C>T p.C134= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV64035464; called by muse, mutect2, varscan2
- KSR1 | c.1866C>T p.D622= (on ENST00000644974 / NM_001367810.1; = p.D507= on NM_014238.2) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs376065082; called by muse, mutect2, varscan2
- LAMB2 | c.2925C>T p.D975= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs1341569224, COSV59734778; called by muse, mutect2, varscan2
- LIG1 | c.2112C>T p.I704= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as rs769895197, COSV54393087; called by muse, mutect2, varscan2
- MYCBPAP | c.1305C>T p.G435= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as rs777887197, COSV60409140; called by muse, mutect2, varscan2
- NARS1 | c.1290C>T p.T430= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as COSV56877298; called by muse, mutect2
- NOL4 | c.432C>G p.A144= | Silent (SNP) | VAF 15/210 reads (7%) | catalogued as COSV52351123; called by muse, mutect2
- NR1H4 | c.45T>C p.S15= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV51853402; called by muse, mutect2
- PRPS1L1 | c.363G>A p.A121= | Silent (SNP) | VAF 60/226 reads (27%) | catalogued as rs548545635, COSV72649925; called by muse, mutect2, varscan2
- RELB | c.1587C>T p.P529= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs770384014, COSV55510863; called by muse, mutect2, varscan2
- SAMSN1 | c.945T>C p.P315= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV53473261; called by muse, mutect2
- SPTA1 | c.3444A>G p.G1148= | Silent (SNP) | VAF 44/430 reads (10%) | catalogued as COSV63755492; called by muse, mutect2, varscan2
- TCF20 | c.1909A>C p.R637= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV59493221; called by muse, mutect2, varscan2
- UGT1A5 | c.591A>G p.L197= | Silent (SNP) | VAF 48/378 reads (13%) | catalogued as COSV59391894; called by muse, mutect2, varscan2
- YTHDC2 | c.1683T>A p.S561= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV50744755; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-455G>C | Intron (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- KNOP1P1 | n.531G>T | RNA (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- OR8A1 | c.-43C>A | 5'UTR (SNP) | VAF 8/82 reads (10%) | catalogued as COSV99420805; called by muse, mutect2, varscan2
- REPIN1 | c.-216C>T | 5'UTR (SNP) | VAF 12/73 reads (16%) | catalogued as COSV101262688; called by muse, mutect2, varscan2
